Somatic mutation profile of tumor specimen TARGET-20-PARTAL-09A (aliquot TARGET-20-PARTAL-09A-02D) from TARGET case TARGET-20-PARTAL, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.4 years (6,000 days).
Specimen TARGET-20-PARTAL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8742d9db-86d2-4540-b4a7-f2500acd0566.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARTAL-14A (Bone Marrow Normal), aliquot TARGET-20-PARTAL-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6da8b2f3-35be-4d28-ae50-a590c141c36e

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 41/110 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATRX | c.6334T>C p.L2112= | Silent (SNP) | VAF 36/107 reads (34%) | called by muse, mutect2, varscan2
- GAREM1 | c.*3700G>T | 3'UTR (SNP) | VAF 93/194 reads (48%) | called by muse, mutect2, varscan2
